Somatic mutation profile of tumor specimen TCGA-AB-2949-03A (aliquot TCGA-AB-2949-03A-01W-0733-08) from TCGA case TCGA-AB-2949, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,336 days).
Specimen TCGA-AB-2949-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3b90cd7-016d-4666-b07b-ee40a8ea371d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2949-11A (Solid Tissue Normal), aliquot TCGA-AB-2949-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abc1ceb6-0b8c-48a0-a7cf-34933520e32a

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1772_1773insAA p.Y591* | Nonsense Mutation (INS) | VAF 23/73 reads (32%) | hotspot (GDC flag); catalogued as COSV60104310, COSV60124684; called by mutect2, varscan2
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CFAP221 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.448); catalogued as COSV54662215, COSV99732868; called by muse, mutect2
- DNAH5 | c.10307G>A p.R3436H | Missense Mutation (SNP) | VAF 31/363 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs771010026, COSV54214061; called by muse, mutect2
- FBXO39 | c.1307T>C p.V436A | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.158); catalogued as COSV100386236, COSV58622528; called by muse, mutect2
- MUC16 | c.31163C>A p.P10388Q | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as rs189284601, COSV101200521; called by muse, mutect2, varscan2
- OR51B6 | c.419T>C p.M140T | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.102); catalogued as COSV100971662; called by muse, mutect2
- ORAI1 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1216488999, COSV57492371; called by muse, varscan2
- PCDHB13 | c.725A>T p.E242V | Missense Mutation (SNP) | VAF 34/606 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.066); catalogued as COSV99507543; called by muse, mutect2
- PCLO | c.8902G>A p.G2968S | Missense Mutation (SNP) | VAF 31/332 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100434814; called by muse, mutect2
- PHF6 | c.976T>C p.C326R | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100136687; called by muse, mutect2
- RELCH | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 11/186 reads (6%) | catalogued as rs1219251716, COSV99901965; called by muse, mutect2
- VLDLR | c.2582C>G p.P861R | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV66078772; called by muse, mutect2, varscan2
- TNFAIP6 | c.168G>T p.A56= | Silent (SNP) | VAF 14/95 reads (15%) | catalogued as COSV99693993; called by muse, mutect2, varscan2
